Gene-level copy-number profile of tumor specimen TARGET-40-PAMRHD-01A from TARGET case TARGET-40-PAMRHD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.8 years (3,942 days).
Specimen TARGET-40-PAMRHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.233d0185-2202-56aa-9474-c93ceeb27e16.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAMRHD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 379 have no estimate.
https://portal.gdc.cancer.gov/files/990d4a3c-9cd6-4c5f-849f-7699edf86e8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 1,846; copy number 2: 32,350; copy number 3: 14,104; copy number 4: 10,087; copy number 5: 584; copy number 6: 246; copy number 7: 503.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,921,328–117,027,039, 4 genes: AC069504.1, LINC00901, RNU5E-8P, PTMAP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,333 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,269,983–43,285,617, 2 genes, copy number 7: TMEM125, C1orf210.
- chr11:130,068,147–135,075,908, 75 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–38,987,383, 684 genes, copy number 6–7 (broad region; genes not listed).
- chr14:41,296,286–47,795,302, 61 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr15:85,180,200–85,234,795, 1 gene, copy number 5 (within-gene range 3–5): AC044860.1.
- chr15:85,191,438–87,029,052, 31 genes, copy number 5 (within-gene range 4–5): CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1, LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1, AC012229.1.
- chr17:31,759,795–31,769,048, 2 genes, copy number 6: GPR160P2, AC007923.1.
- chr17:69,414,697–69,553,865, 1 gene, copy number 5 (within-gene range 4–5): MAP2K6.
- chr17:69,477,139–83,095,122, 476 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,846. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
